Somatic mutation profile of tumor specimen TCGA-94-8035-01A (aliquot TCGA-94-8035-01A-11D-2244-08) from TCGA case TCGA-94-8035, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 64.1 years (23,399 days).
Specimen TCGA-94-8035-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d041dd32-42e0-4cdb-a2b8-0745231848ba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-94-8035-10A (Blood Derived Normal), aliquot TCGA-94-8035-10A-01D-2244-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc0b41cd-71d2-4efc-bdb7-b9013ae594c5

The open-access MAF lists 224 somatic variants for this specimen: 162 protein-altering or splice-affecting, 58 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 142, Silent 58, Frame Shift Del 7, Nonsense Mutation 7, Splice Site 3, Splice Region 2, RNA 2, 3'Flank 1, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.590T>G p.V197G | Missense Mutation (SNP) | VAF 10/44 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM994748, COSV52661145, COSV52810143, COSV53120183; called by muse, mutect2, varscan2
- ABCB5 | c.2813G>C p.R938P (on ENST00000404938 / NM_001163941.2; = p.R493P on NM_178559.6) | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV51708937, COSV51714265, COSV99328970; called by muse, mutect2, varscan2
- ABCG5 | c.636G>A p.K212= | Splice Region (SNP) | VAF 16/128 reads (13%) | catalogued as rs1229923300, COSV99575503; called by muse, mutect2, varscan2
- ADAM7 | c.1303G>T p.V435L | Missense Mutation (SNP) | VAF 36/191 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.011); catalogued as COSV99444459; called by muse, mutect2, varscan2
- ADCY8 | c.2530A>G p.M844V | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.704); catalogued as COSV99653262; called by muse, mutect2, varscan2
- ADGRB1 | c.3457G>A p.A1153T | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100030011, COSV60104680; called by muse, mutect2
- ADGRG6 | c.767T>C p.V256A | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV99747970; called by muse, mutect2
- ADH1C | c.768G>T p.K256N | Missense Mutation (SNP) | VAF 32/314 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.135); catalogued as rs1254725879, COSV101565162, COSV101565190; called by muse, varscan2
- AKAP9 | c.1908G>T p.E636D | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100662709; called by muse, mutect2, varscan2
- ALDH8A1 | c.1343G>T p.W448L | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99664882; called by muse, mutect2, varscan2
- ALDH8A1 | c.1342T>G p.W448G | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754529921, COSV99664884; called by muse, mutect2, varscan2
- ALLC | c.1162A>C p.K388Q | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.025); catalogued as COSV99378054; called by muse, mutect2
- AMBN | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 46/81 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as rs1451949624, COSV100534413; called by muse, mutect2, varscan2
- AMY1C | c.968G>C p.G323A | Missense Mutation (SNP) | VAF 22/440 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs760285981; called by muse, mutect2
- ARHGEF2 | c.797T>G p.L266R (on ENST00000361247 / NM_001162383.2; = p.L238R on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV100560814; called by muse, mutect2, varscan2
- ARMCX2 | c.827G>C p.G276A | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.142); catalogued as COSV100168224; called by muse, varscan2
- ASRGL1 | c.430A>C p.N144H | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.202); catalogued as rs758258713, COSV100078009; called by muse, varscan2
- ATF6 | c.473G>T p.R158M | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.112); catalogued as COSV100909328; called by muse, mutect2, varscan2
- ATF7IP2 | c.1037A>G p.Q346R | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV100202697; called by muse, mutect2, varscan2
- ATG2A | c.4843G>T p.E1615* | Nonsense Mutation (SNP) | VAF 22/133 reads (17%) | catalogued as COSV101034602; called by muse, mutect2, varscan2
- ATP1A2 | c.1165A>G p.M389V | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.047); catalogued as COSV100768003; called by muse, mutect2, varscan2
- ATP2B2 | c.1842G>T p.K614N (on ENST00000352432; = p.K580N on NM_001683.5) | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100660207; called by muse, mutect2
- ATP5F1B | c.1454A>T p.K485M | Missense Mutation (SNP) | VAF 41/199 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.607); catalogued as COSV99466945; called by muse, mutect2, varscan2
- BAIAP2 | c.452G>T p.S151I | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100348531; called by muse, mutect2, varscan2
- BTN2A2 | c.1246G>A p.G416S | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1044348411, COSV100760509; called by muse, mutect2
- C12orf71 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.767); catalogued as rs889074014, COSV101460538; called by muse, mutect2, varscan2
- C6orf118 | c.722C>A p.A241E | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.774); catalogued as COSV100024787; called by muse, mutect2, varscan2
- CABCOCO1 | c.150G>C p.K50N | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.647); catalogued as rs1415261004, COSV100357984; called by muse, mutect2, varscan2
- CALCR | c.968C>A p.A323E (on ENST00000649521 / NM_001164737.2; = p.A307E on NM_001742.4) | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100810692, COSV64006212; called by muse, mutect2, varscan2
- CASQ1 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 46/247 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs979091500, COSV100927256, COSV100927337; called by muse, mutect2, varscan2
- CCDC27 | c.591C>G p.F197L | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV53899391, COSV99622758; called by muse, mutect2, varscan2
- CCN3 | c.390G>C p.Q130H | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV99423166; called by muse, mutect2, varscan2
- CCPG1 | c.688G>T p.G230* | Nonsense Mutation (SNP) | VAF 19/96 reads (20%) | catalogued as COSV100197292; called by muse, mutect2, varscan2
- CCPG1 | c.687G>T p.M229I | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100197294; called by muse, mutect2, varscan2
- CCT6B | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.197); catalogued as COSV100030865; called by muse, mutect2
- CD1E | c.998+2T>A p.X333_splice | Splice Site (SNP) | VAF 11/33 reads (33%) | catalogued as COSV100937033; called by muse, mutect2, varscan2
- CDH10 | c.2150G>T p.R717M | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52584402; called by muse, mutect2, varscan2
- CHEK2 | c.1138T>G p.Y380D (on ENST00000382580 / NM_001005735.2; = p.Y337D on NM_007194.4) | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100102107; called by muse, mutect2, varscan2
- CHRND | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376642208; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CMTR1 | c.2089G>T p.D697Y | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV100990895, COSV65090264; called by muse, mutect2, varscan2
- CNKSR2 | c.2307G>T p.Q769H | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.21); catalogued as COSV54260563, COSV99669225; called by muse, mutect2, varscan2
- CNTNAP5 | c.899C>A p.A300D | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV101443361, COSV101443837; called by muse, mutect2, varscan2
- COL4A6 | c.2420G>A p.G807E | Missense Mutation (SNP) | VAF 45/87 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100564599; called by muse, mutect2, varscan2
- COL9A2 | c.314G>A p.G105E | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775128466, COSV101025738, COSV65607104; called by muse, mutect2, varscan2
- CRB1 | c.3310G>A p.G1104S | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs954823148, COSV100957984; called by muse, mutect2, varscan2
- CYTH3 | c.623A>T p.N208I | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100641529, COSV100641694; called by muse, mutect2, varscan2
- DNM3 | c.869G>T p.R290L | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV100798457; called by muse, mutect2, varscan2
- DUOX2 | c.1073A>G p.N358S | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.014); catalogued as COSV100545919; called by muse, mutect2, varscan2
- DZIP3 | c.3616C>T p.P1206S | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.033); catalogued as rs764802925, COSV100847932; called by muse, mutect2, varscan2
- EPG5 | c.2770C>G p.L924V | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.69); PolyPhen benign (0.09); catalogued as COSV99957704; called by muse, mutect2, varscan2
- EVI5 | c.220T>G p.S74A | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.05); catalogued as COSV100945441; called by muse, mutect2, varscan2
- FADS6 | c.823C>T p.R275W | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.233); catalogued as rs375851737; called by muse, mutect2
- FAM135B | c.3140T>C p.V1047A | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.051); catalogued as COSV99425767; called by muse, mutect2, varscan2
- FLNC | c.7061C>A p.P2354H | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100368428; called by muse, mutect2, varscan2
- HERC2 | c.3629T>C p.I1210T | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs545686064, COSV55352769; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HJURP | c.1161G>T p.L387F | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.656); catalogued as COSV100982616; called by muse, mutect2, varscan2
- HMGB4 | c.344A>G p.N115S | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.829); catalogued as COSV99592595; called by muse, mutect2, varscan2
- HOXA4 | c.836C>G p.T279S | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100415578; called by muse, mutect2, varscan2
- IARS2 | c.1885G>C p.G629R | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.51); PolyPhen probably damaging (1); catalogued as COSV100228643; called by muse, mutect2, varscan2
- IGF2R | c.668C>G p.S223* | Nonsense Mutation (SNP) | VAF 8/81 reads (10%) | catalogued as COSV100807799; called by muse, mutect2, varscan2
- INSR | c.3043G>A p.E1015K | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as rs147176789; called by muse, mutect2, varscan2
- ITGB4 | c.2785G>A p.A929T | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs143240391; called by muse, mutect2, varscan2
- JAG1 | c.2866G>T p.D956Y | Missense Mutation (SNP) | VAF 51/305 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV99653216; called by muse, mutect2, varscan2
- KATNIP | c.1763A>G p.K588R | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.275); catalogued as COSV99851573; called by muse, mutect2, varscan2
- KDM6A | c.3489C>A p.D1163E | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100938430; called by muse, mutect2, varscan2
- KIAA1217 | c.1948A>T p.R650W | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100286938; called by muse, mutect2, varscan2
- KIF2B | c.224C>A p.T75N | Missense Mutation (SNP) | VAF 79/286 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.299); catalogued as COSV99275798; called by muse, mutect2, varscan2
- KIRREL2 | c.360G>A p.L120= | Splice Region (SNP) | VAF 19/91 reads (21%) | catalogued as COSV99384199; called by muse, mutect2, varscan2
- KRTAP10-12 | c.623G>C p.R208P | Missense Mutation (SNP) | VAF 11/289 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs576036099; called by muse, mutect2
- LARGE1 | c.1693G>T p.D565Y | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100505970; called by muse, mutect2
- LILRB4 | c.956G>T p.S319I | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV99553994; called by muse, mutect2, varscan2
- LPAR2 | c.52A>G p.N18D | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); catalogued as COSV99179394; called by muse, mutect2, varscan2
- LRP1B | c.5082G>T p.K1694N | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); catalogued as COSV101258264; called by muse, mutect2, varscan2
- MAGEE2 | c.673C>A p.L225I | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.214); catalogued as COSV100973164; called by muse, mutect2, varscan2
- MKRN3 | c.130C>A p.P44T | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.017); catalogued as COSV100091396, COSV58810358; called by muse, mutect2, varscan2
- MUC16 | c.22249T>A p.S7417T | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.179); catalogued as COSV101200519; called by muse, mutect2, varscan2
- MYCBPAP | c.455G>A p.R152Q | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.155); catalogued as rs759727010, COSV100088622, COSV100089304; called by muse, mutect2, varscan2
- MYH1 | c.664C>G p.Q222E | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV99876452; called by muse, mutect2, varscan2
- MYH15 | c.57A>G p.I19M | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV99843844; called by muse, mutect2
- MYLK4 | c.51C>G p.N17K | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.015); catalogued as rs757954497, COSV51148238; called by muse, mutect2, varscan2
- MYO5C | c.610G>T p.V204F | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV99955082; called by muse, mutect2
- MYOD1 | c.646C>A p.P216T | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs768887479, COSV100000336, COSV99031720; called by muse, mutect2, varscan2
- NCOA3 | c.3979C>T p.R1327* (on ENST00000371998 / NM_181659.3; = p.R1323* on NM_006534.4) | Nonsense Mutation (SNP) | VAF 27/106 reads (25%) | catalogued as COSV100507865; called by muse, mutect2, varscan2
- NETO1 | c.187C>A p.P63T | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55003612, COSV55013291; called by muse, mutect2, varscan2
- NFE2 | c.227T>A p.F76Y | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV100380806; called by muse, mutect2, varscan2
- NIBAN2 | c.289G>T p.G97W | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs370720142, COSV100964846; called by muse, mutect2, varscan2
- NLGN1 | c.1855A>G p.I619V | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV100849730; called by muse, mutect2, varscan2
- NLRC5 | c.1699G>T p.G567C | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs766650347, COSV99347789; called by muse, mutect2, varscan2
- NLRP12 | c.1399G>A p.D467N | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as COSV100145534; called by muse, mutect2, varscan2
- NRG3 | c.1746G>T p.L582F (on ENST00000404547 / NM_001370084.1; = p.L558F on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/202 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.893); catalogued as COSV100930769, COSV64557849; called by muse, mutect2, varscan2
- NRIP1 | c.715A>G p.R239G | Missense Mutation (SNP) | VAF 47/178 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100012881; called by muse, mutect2, varscan2
- NRIP1 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV100012882; called by muse, mutect2
- NT5DC3 | c.988G>T p.E330* | Nonsense Mutation (SNP) | VAF 35/225 reads (16%) | catalogued as COSV101231005; called by muse, mutect2, varscan2
- ODF1 | c.366C>G p.S122R | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV99574315; called by muse, mutect2, varscan2
- OR10K2 | c.168T>A p.H56Q | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV100149575; called by muse, mutect2, varscan2
- OR14A16 | c.434T>G p.V145G | Missense Mutation (SNP) | VAF 25/176 reads (14%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.643); catalogued as COSV100713815; called by muse, mutect2, varscan2
- OR4A5 | c.731T>C p.V244A | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as rs752490983, COSV100157214; called by muse, varscan2
- OR4K14 | c.728C>A p.A243E | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100520480; called by muse, mutect2
- OR4N2 | c.782C>A p.P261H | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60056053; called by muse, mutect2, varscan2
- OR5M10 | c.57C>A p.D19E | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV101595911, COSV73242308; called by muse, mutect2, varscan2
- OR6K2 | c.130G>A p.V44I | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV100656833, COSV62743843; called by muse, mutect2, varscan2
- OVCH1 | c.2284G>A p.D762N | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV100548940; called by muse, mutect2
- PCDHGA11 | c.1990G>T p.A664S | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV99542466; called by muse, mutect2, varscan2
- PGBD1 | c.1465G>C p.V489L | Missense Mutation (SNP) | VAF 32/167 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99460633; called by muse, mutect2, varscan2
- PIP5K1C | c.1496C>T p.T499M | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.071); catalogued as rs894650136, COSV58956689; called by muse, mutect2, varscan2
- PKHD1 | c.9623C>A p.T3208N | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100583834; called by muse, mutect2, varscan2
- PLXNA4 | c.4141C>T p.R1381C | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1174677476, COSV58104016; called by muse, mutect2
- PMP2 | c.326T>A p.L109Q | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV99808276; called by muse, mutect2, varscan2
- POTEE | c.487G>T p.D163Y | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.585); catalogued as COSV100388460, COSV58246819; called by muse, mutect2, varscan2
- POTEE | c.1219A>G p.I407V | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as COSV100388461; called by muse, mutect2, varscan2
- PRAMEF15 | c.1090A>G p.I364V | Missense Mutation (SNP) | VAF 77/274 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs1202494022; called by muse, mutect2, varscan2
- PTPRO | c.2512C>T p.L838F | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV99841176; called by muse, mutect2, varscan2
- RAB17 | c.107C>G p.A36G | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV99221369, COSV99221383; called by muse, mutect2, varscan2
- RANBP6 | c.1829C>T p.S610F | Missense Mutation (SNP) | VAF 33/323 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99424280; called by muse, mutect2, varscan2
- RPS6KA4 | c.973G>T p.E325* | Nonsense Mutation (SNP) | VAF 22/86 reads (26%) | catalogued as COSV99590267; called by muse, mutect2, varscan2
- RRBP1 | c.13G>A p.D5N | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs548871048, COSV99854304; called by muse, mutect2, varscan2
- SCN11A | c.4918T>C p.F1640L | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100182007; called by muse, mutect2, varscan2
- SCNN1G | c.1414C>T p.P472S | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100264343; called by muse, mutect2
- SERPINA1 | c.101A>G p.K34R | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.065); catalogued as COSV100872153; called by muse, mutect2, varscan2
- SIGLEC1 | c.4998-2A>T p.X1666_splice | Splice Site (SNP) | VAF 34/167 reads (20%) | catalogued as rs1377656142, COSV99169687; called by muse, mutect2, varscan2
- SIX4 | c.1304C>G p.S435C | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.841); catalogued as COSV99382397; called by muse, mutect2, varscan2
- SLC2A2 | c.529G>A p.G177S | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.153); catalogued as rs144822218, COSV100049387, COSV100049461; called by muse, mutect2, varscan2
- SLC35G2 | c.626T>C p.L209S | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101262071; called by muse, mutect2, varscan2
- SLC5A6 | c.1016A>T p.Y339F | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as COSV100143417; called by muse, mutect2, varscan2
- SLC7A4 | c.1804T>A p.S602T | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100298796; called by muse, mutect2, varscan2
- SPTA1 | c.4772A>T p.H1591L | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV100935246; called by muse, mutect2, varscan2
- SPTB | c.694C>A p.H232N | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); catalogued as COSV101072301; called by muse, mutect2, varscan2
- SSH2 | c.2756C>G p.P919R | Missense Mutation (SNP) | VAF 57/254 reads (22%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.024); catalogued as rs376316249; called by muse, mutect2, varscan2
- TAS2R20 | c.531G>T p.L177F | Missense Mutation (SNP) | VAF 51/260 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.835); catalogued as COSV101115209; called by muse, mutect2, varscan2
- TBC1D2B | c.2683A>G p.I895V | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs773860917, COSV100317516; called by muse, varscan2
- TMC4 | c.1767C>G p.F589L (on ENST00000617472 / NM_001145303.3; = p.F583L on NM_144686.4) | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.106); catalogued as COSV99714036; called by muse, mutect2, varscan2
- TMPRSS11F | c.1237T>A p.C413S | Missense Mutation (SNP) | VAF 79/151 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100678683; called by muse, mutect2, varscan2
- TSHZ2 | c.685G>T p.E229* | Nonsense Mutation (SNP) | VAF 8/42 reads (19%) | catalogued as COSV100296456; called by muse, mutect2, varscan2
- TTN | c.75862G>A p.E25288K (on ENST00000591111; = p.E17864K on NM_003319.4) | Missense Mutation (SNP) | VAF 12/120 reads (10%) | PolyPhen benign (0.085); catalogued as rs878894717, COSV100621299; called by muse, mutect2, varscan2
- TTN | c.12664A>T p.N4222Y (on ENST00000591111; = p.N4176Y on NM_003319.4) | Missense Mutation (SNP) | VAF 5/39 reads (13%) | catalogued as COSV100621300; called by muse, mutect2
- TUT4 | c.245G>T p.G82V | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.422); catalogued as COSV99932583; called by muse, mutect2
- TXNDC16 | c.1451G>T p.G484V | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV99909412; called by muse, mutect2
- UMODL1 | c.263G>A p.R88K | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.824); catalogued as COSV101253441; called by muse, mutect2, varscan2
- UNC13C | c.1670G>T p.C557F | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV52856227, COSV99520605; called by muse, mutect2, varscan2
- WDPCP | c.1625-2A>T p.X542_splice | Splice Site (SNP) | VAF 13/84 reads (15%) | catalogued as COSV99705949; called by muse, mutect2, varscan2
- WDR49 | c.1224del p.K409Sfs*23 (on ENST00000308378 / NM_001366158.1; = p.K750Sfs*23 on NM_001348951.2 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 25/152 reads (16%) | catalogued as COSV57701911, COSV57702479; called by mutect2, pindel, varscan2
- YME1L1 | c.1834G>C p.D612H (on ENST00000326799 / NM_139312.3; = p.D555H on NM_014263.4) | Missense Mutation (SNP) | VAF 11/140 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.733); catalogued as COSV100463153, COSV100463934; called by muse, mutect2
- ZAN | c.1946T>G p.I649S | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV100769957; called by muse, mutect2, varscan2
- ZFHX3 | c.2596C>G p.L866V | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99213759; called by muse, mutect2, varscan2
- ZFP1 | c.145G>T p.V49L | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.054); catalogued as COSV100182113; called by muse, mutect2, varscan2
- ZIK1 | c.1424G>T p.C475F | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.033); catalogued as COSV100277570; called by muse, mutect2, varscan2
- ZNF273 | c.477C>A p.H159Q | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.058); catalogued as COSV100139312, COSV100139438; called by muse, mutect2, varscan2
- ZNF284 | c.1356G>C p.E452D | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101399038; called by muse, mutect2, varscan2
- ZNF362 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs746967426, COSV100987028; called by muse, mutect2, varscan2
- ZNF383 | c.540T>A p.S180R | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.023); catalogued as COSV100776782; called by muse, mutect2, varscan2
- ZNF699 | c.1012A>G p.K338E | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as COSV58025381; called by muse, mutect2, varscan2
- ZNF831 | c.2611G>A p.E871K | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.67); PolyPhen benign (0.005); catalogued as rs1162355769, COSV64040765; called by muse, mutect2, varscan2
- ZSCAN1 | c.964T>G p.C322G | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99991852; called by muse, mutect2, varscan2
- CLIP1 | c.3551dup p.E1185Gfs*24 (on ENST00000620786 / NM_001247997.1; = p.E1174Gfs*24 on NM_002956.2) | Frame Shift Ins (INS) | VAF 16/69 reads (23%) | called by mutect2, pindel, varscan2
- FOXP1 | c.1240del p.L414* | Frame Shift Del (DEL) | VAF 50/162 reads (31%) | called by mutect2, varscan2
- IKZF3 | c.1314_1317del p.V439Kfs*2 | Frame Shift Del (DEL) | VAF 29/248 reads (12%) | called by mutect2, pindel, varscan2
- KIR2DL4 | c.1028A>G p.D343G (on ENST00000396284; = p.D269G on NM_001080770.2) | Missense Mutation (SNP) | VAF 56/334 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- MAGEA8 | c.274G>C p.E92Q | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- OR11L1 | c.10del p.Q4Kfs*6 | Frame Shift Del (DEL) | VAF 16/58 reads (28%) | called by mutect2, pindel, varscan2
- OR4A16 | c.542del p.P181Hfs*13 | Frame Shift Del (DEL) | VAF 83/347 reads (24%) | called by mutect2, pindel, varscan2
- PDS5B | c.3271_3272del p.P1091Gfs*11 | Frame Shift Del (DEL) | VAF 21/127 reads (17%) | called by mutect2, pindel, varscan2
- SCNN1D | c.552del p.F185Sfs*12 (on ENST00000338555; = p.F349Sfs*12 on NM_001130413.4) | Frame Shift Del (DEL) | VAF 67/184 reads (36%) | called by mutect2, pindel, varscan2
- ABT1 | c.510C>G p.R170= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as COSV99223302; called by muse, mutect2, varscan2
- ACAP2 | c.1023C>G p.L341= | Silent (SNP) | VAF 22/202 reads (11%) | catalogued as rs781152068, COSV58751393; called by muse, mutect2, varscan2
- ARFGEF3 | c.2595G>T p.L865= | Silent (SNP) | VAF 56/255 reads (22%) | catalogued as COSV99294171; called by muse, mutect2, varscan2
- ATM | c.1779A>T p.T593= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as COSV99590664; called by muse, mutect2, varscan2
- BRINP2 | c.1782G>T p.G594= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV100838214; called by muse, mutect2, varscan2
- BRS3 | c.204C>T p.L68= | Silent (SNP) | VAF 5/79 reads (6%) | catalogued as COSV101036619; called by muse, mutect2
- BTNL9 | c.294G>A p.P98= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as rs761241837, COSV59793183; called by muse, mutect2, varscan2
- CASS4 | c.862A>C p.R288= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV100824802; called by muse, mutect2, varscan2
- CCNT1 | c.171G>A p.L57= | Silent (SNP) | VAF 10/65 reads (15%) | catalogued as COSV99980832; called by muse, mutect2
- CCR10 | c.888C>T p.S296= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs758868599, COSV99226739; called by mutect2, varscan2
- CDH12 | c.51A>G p.G17= | Silent (SNP) | VAF 14/346 reads (4%) | catalogued as COSV101202963; called by muse, mutect2
- CNST | c.1110G>A p.T370= | Silent (SNP) | VAF 12/111 reads (11%) | catalogued as rs140541041; called by muse, mutect2, varscan2
- DNAJC25 | c.387G>A p.E129= | Silent (SNP) | VAF 36/113 reads (32%) | catalogued as COSV100543409; called by muse, mutect2, varscan2
- DPPA3 | c.411G>A p.V137= | Silent (SNP) | VAF 37/162 reads (23%) | catalogued as COSV100559954; called by muse, mutect2, varscan2
- EPHA3 | c.456C>T p.F152= | Silent (SNP) | VAF 10/170 reads (6%) | catalogued as COSV100345999; called by muse, mutect2
- EPPK1 | c.4851C>T p.P1617= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as rs782792511, COSV101599906, COSV73262410; called by muse, mutect2, varscan2
- FCRL5 | c.1710C>A p.L570= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as COSV100709122; called by muse, mutect2
- FRMPD3 | c.3843G>A p.E1281= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as COSV99346733; called by muse, mutect2, varscan2
- H2BC18 | c.147C>T p.V49= | Silent (SNP) | VAF 24/522 reads (5%) | catalogued as rs782141644, COSV100516143, COSV58943754, COSV58944034; called by muse, mutect2
- HGSNAT | c.1890G>A p.K630= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV99925374; called by muse, mutect2
- ICA1 | c.492G>T p.T164= | Silent (SNP) | VAF 30/142 reads (21%) | catalogued as COSV104377038, COSV99655591; called by muse, mutect2, varscan2
- IGKV2D-24 | c.342G>C p.T114= | Silent (SNP) | VAF 62/289 reads (21%) | catalogued as rs370493862; called by muse, mutect2, varscan2
- ITGA9 | c.1848T>C p.F616= | Silent (SNP) | VAF 33/107 reads (31%) | catalogued as COSV99293354; called by muse, mutect2, varscan2
- ITPR3 | c.5052C>T p.N1684= | Silent (SNP) | VAF 15/117 reads (13%) | catalogued as COSV100967701; called by muse, mutect2, varscan2
- KCNMB2 | c.210G>T p.L70= | Silent (SNP) | VAF 299/627 reads (48%) | catalogued as COSV100843997; called by muse, mutect2, varscan2
- LATS1 | c.855C>A p.I285= | Silent (SNP) | VAF 24/130 reads (18%) | catalogued as COSV53598627; called by muse, mutect2, varscan2
- MAGI2 | c.585A>G p.L195= | Silent (SNP) | VAF 74/318 reads (23%) | catalogued as COSV100835469; called by muse, mutect2, varscan2
- MAPRE1 | c.720G>A p.Q240= | Silent (SNP) | VAF 51/210 reads (24%) | catalogued as COSV100980404; called by muse, mutect2, varscan2
- MAPRE3 | c.141C>T p.F47= | Silent (SNP) | VAF 5/98 reads (5%) | catalogued as COSV99251931; called by muse, mutect2
- MERTK | c.936C>T p.S312= | Silent (SNP) | VAF 11/84 reads (13%) | catalogued as COSV99774960; called by muse, mutect2, varscan2
- MYO5A | c.4524A>G p.L1508= | Silent (SNP) | VAF 54/242 reads (22%) | catalogued as COSV100697898; called by muse, mutect2, varscan2
- MYOZ3 | c.636G>A p.R212= | Silent (SNP) | VAF 31/135 reads (23%) | catalogued as rs774800798, COSV99770808; called by muse, mutect2, varscan2
- NCAM2 | c.978G>T p.G326= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as COSV53073583; called by muse, mutect2, varscan2
- NR0B1 | c.297G>T p.A99= | Silent (SNP) | VAF 17/35 reads (49%) | catalogued as COSV100973536, COSV66763951; called by muse, mutect2, varscan2
- OR4C13 | c.183G>A p.L61= | Silent (SNP) | VAF 85/292 reads (29%) | catalogued as rs148216632; called by muse, mutect2, varscan2
- OXNAD1 | c.90C>T p.L30= | Silent (SNP) | VAF 47/140 reads (34%) | catalogued as COSV99551326; called by muse, mutect2, varscan2
- PPP2R3A | c.3399A>G p.L1133= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV99387757; called by muse, mutect2, varscan2
- PRAG1 | c.3171G>T p.S1057= | Silent (SNP) | VAF 20/103 reads (19%) | catalogued as COSV100422481; called by muse, mutect2, varscan2
- PRAG1 | c.2442A>T p.P814= | Silent (SNP) | VAF 16/84 reads (19%) | catalogued as rs1224935231, COSV100422487; called by mutect2, varscan2
- PRODH2 | c.675C>A p.P225= (on ENST00000301175; = p.P149= on NM_021232.2 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV56558611, COSV99995398; called by muse, mutect2, varscan2
- SEL1L3 | c.624C>T p.I208= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as COSV99340765; called by muse, mutect2, varscan2
- SHB | c.747C>T p.P249= | Silent (SNP) | VAF 28/86 reads (33%) | catalogued as rs1426813630, COSV100891046, COSV100891072; called by muse, mutect2, varscan2
- SLC26A3 | c.564C>A p.I188= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV100385197; called by muse, mutect2
- SLC4A10 | c.480T>A p.A160= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as COSV55784777, COSV99764930; called by muse, mutect2, varscan2
- SLITRK4 | c.231T>C p.N77= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as COSV100567433; called by muse, mutect2, varscan2
- SMARCA1 | c.2772A>G p.A924= | Silent (SNP) | VAF 34/79 reads (43%) | catalogued as COSV100946632; called by muse, mutect2, varscan2
- SPRING1 | c.63G>C p.L21= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as COSV99732397; called by mutect2, varscan2
- ST14 | c.939C>G p.L313= | Silent (SNP) | VAF 22/220 reads (10%) | catalogued as COSV53834104; called by muse, mutect2
- SV2A | c.402G>T p.G134= | Silent (SNP) | VAF 29/122 reads (24%) | catalogued as COSV100975215, COSV64964352; called by muse, mutect2, varscan2
- SYNE2 | c.18942C>T p.S6314= | Silent (SNP) | VAF 29/113 reads (26%) | catalogued as rs146572710, COSV59959464; called by muse, mutect2, varscan2
- TBATA | c.288G>A p.G96= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV54719369; called by muse, mutect2, varscan2
- TTC38 | c.279G>A p.V93= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as COSV101123917; called by muse, mutect2, varscan2
- TXLNB | c.2019C>T p.R673= | Silent (SNP) | VAF 15/71 reads (21%) | catalogued as COSV100625090; called by muse, mutect2, varscan2
- U2SURP | c.105A>T p.G35= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV101204535; called by muse, mutect2, varscan2
- WDR1 | c.246G>A p.L82= | Silent (SNP) | VAF 5/95 reads (5%) | catalogued as COSV99306064; called by muse, mutect2
- ZNF292 | c.4632C>T p.N1544= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as rs1245369094, COSV100370759; called by muse, mutect2
- ZNF548 | c.117G>A p.E39= | Silent (SNP) | VAF 18/647 reads (3%) | catalogued as COSV60241472; called by muse, mutect2
- ZSWIM5 | c.1692C>T p.A564= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as COSV100655678; called by muse, mutect2, varscan2
- BAGE2 | n.282C>A | RNA (SNP) | VAF 8/195 reads (4%) | catalogued as rs1468471491; called by muse, mutect2
- OR8G5 | c.-8A>T | 5'UTR (SNP) | VAF 7/32 reads (22%) | catalogued as rs1181555469, COSV100422550; called by muse, mutect2
- POM121 | chr7:72949080 C>T | 3'Flank (SNP) | VAF 6/90 reads (7%) | catalogued as COSV99988777; called by muse, mutect2
- SH2D6 | n.439G>A | RNA (SNP) | VAF 10/27 reads (37%) | catalogued as COSV100442567; called by muse, mutect2, varscan2
